Somatic mutation profile of tumor specimen 0DBNBF from CCDI case PBBLCW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pigmented dermatofibrosarcoma protuberans; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 2.1 years (781 days).
Specimen 0DBNBF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14d6b9c2-7580-4cec-a1bb-a901305b4dbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DBNBN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b83b5b0a-d90d-400f-b1e0-3db4995585c5

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Frame Shift Ins 1, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGR2 | c.184dup p.I62Nfs*2 | Frame Shift Ins (INS) | VAF 118/850 reads (14%) | called by mutect2, varscan2
- EXOC3L4 | c.1472G>A p.S491N | Missense Mutation (SNP) | VAF 148/536 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ACSM2B | c.1692A>G p.R564= | Silent (SNP) | VAF 72/744 reads (10%) | called by muse, mutect2
- VIPR1 | c.*37G>A | 3'UTR (SNP) | VAF 44/148 reads (30%) | catalogued as COSV57298862; called by muse, mutect2, varscan2
